Surgical pathology report (de-identified scan), TCGA case TCGA-HE-A5NL, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HE-A5NL-01A (Primary Tumor).

Sample Number

Sample Type TUMOUR

Diagnosis	PAPILLARY RENAL CELL CARCINOMA TYPE I
Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	
Type of Procedure	RESECT
Site of Tissue/Primary (Histology)	RIGHT PARTIAL KIDNEY
Tumour Size (cm)	3.5
Histology	PAPILLARY RENAL CELL CARCINOMA TYPE I
Grade/Differentiation	II
Pathological T	T1a
Pathological N	NX
Clinical M	M0
Histology Comments	

Sample Number

Sample Type BUFFY

Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	

ICD-O-3
Carcinoma, papillary renal cell
Site: @ Kidney NOS C64.9
JW 2/11/13

Criteria JW 2/7/13

HUPA Discrepancy		

Source: NCI Genomic Data Commons file 5e5f5858-1d0f-4724-a307-12ee149f2b79 (TCGA-HE-A5NL.97B0BE36-91DE-4A1F-A940-737C731BDCEC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).